FM case AD16911 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/39604cc9-1aaf-4ce8-a0dd-2f3ec5aa4e5c

Male, 73.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the small intestine. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
